Somatic mutation profile of tumor specimen TCGA-VP-A87B-01A (aliquot TCGA-VP-A87B-01A-11D-A34U-08) from TCGA case TCGA-VP-A87B, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.7 years (23,271 days).
Specimen TCGA-VP-A87B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e2171d-841d-47e8-a43f-77c907105226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87B-10A (Blood Derived Normal), aliquot TCGA-VP-A87B-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32fd5d34-aa10-4aff-aef2-167f5b541655

The open-access MAF lists 33 somatic variants for this specimen: 30 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 27, Silent 3, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 71/171 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKRD49 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV100119434; called by muse, mutect2, varscan2
- AP4B1 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 152/372 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.138); catalogued as COSV99870522; called by muse, mutect2, varscan2
- ART4 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV99966805; called by muse, mutect2, varscan2
- BBS9 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54177452; called by muse, mutect2, varscan2
- CNOT1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100408461; called by muse, mutect2
- DBF4 | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99719127; called by muse, mutect2
- DDO | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100927805; called by muse, mutect2, varscan2
- DLEC1 | c.3932G>C p.G1311A | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100341406; called by muse, mutect2, varscan2
- DOCK4 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs202157965; called by muse, mutect2, varscan2
- ERBB2 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143958183; called by muse, mutect2, varscan2
- EXOC3L1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99333404; called by muse, mutect2, varscan2
- EYS | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100675625; called by muse, mutect2, varscan2
- HAUS4 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99246740; called by muse, mutect2, varscan2
- HPR | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99930758; called by muse, mutect2, varscan2
- LILRB5 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs760446124, COSV100300041; called by muse, mutect2, varscan2
- MAD1L1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753461846, COSV56234500; called by muse, mutect2
- MROH9 | c.947T>C p.L316S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100882679; called by muse, mutect2, varscan2
- NRG1 | c.754G>T p.A252S (on ENST00000405005 / NM_013964.5; = p.A257S on NM_013956.5) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs771092162, COSV55152234, COSV99827524; called by muse, mutect2, varscan2
- NSD1 | c.5458G>A p.V1820M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752685166, COSV61773772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10P1 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374333859, COSV59007681; called by muse, mutect2
- OSBPL3 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV100513654; called by muse, mutect2, varscan2
- PCDHGA8 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99530075; called by muse, mutect2, varscan2
- PCLO | c.11461C>T p.R3821* | Nonsense Mutation (SNP) | VAF 63/109 reads (58%) | catalogued as COSV100427137; called by muse, mutect2, varscan2
- PDE2A | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771749226, COSV57805769; called by muse, mutect2, varscan2
- SLC28A2 | c.263-2A>T p.X88_splice | Splice Site (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100754608; called by muse, mutect2, varscan2
- SYNDIG1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770624311, COSV65232499; called by muse, mutect2, varscan2
- TBC1D4 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.375); catalogued as rs1360577447, COSV100884517; called by muse, mutect2, varscan2
- TRIM16L | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767983916, COSV101192578; called by muse, mutect2, varscan2
- USH2A | c.6775G>A p.V2259I | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56326286; called by muse, mutect2, varscan2
- KIF17 | c.2352C>T p.A784= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99928474, COSV99929457; called by muse, mutect2, varscan2
- WBP11 | c.1596G>T p.G532= | Silent (SNP) | VAF 131/290 reads (45%) | catalogued as COSV53765069, COSV99660529; called by muse, mutect2, varscan2
- ZDHHC9 | c.915G>A p.E305= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV100852102; called by muse, mutect2, varscan2
